Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6526, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6526-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

Examination: Histopathological examination

[REDACTED]

Material: Multiple organ resection – stomach

[REDACTED]

PROGRAM HER-2 /stomach

[REDACTED] TCGA – D7 – 6526

Physician in charge: [REDACTED]

Material collected on: [REDACTED] Material received on: [REDACTED]

Expected time of examination: [REDACTED]

Clinical diagnosis: Cancer of the stomach. Total gastrectomy.

[REDACTED]

Macroscopic description:

Sent material consisting of the stomach, cut out along the greater curvature, sized 18 x 19 cm with the omentum sized 32 x 17 cm. Tumour sized 8 x 6.5 x 2 cm in the pyloric region. Macroscopically, the invasion covering the perigastric fat tissue. Distance from the proximal end 5 cm, from distal end 0.8 cm.

Microscopic description:

Adenocarcinoma tubulare G2.

Tumour penetrating the full thickness of the stomach wall, the perigastric fat tissue and blood vessels.

Surgical incision lines free of cancer invasion.

Metastases carcinomatosae in lymphonodis No. III/XIX.

Infiltratio capsulae lymphonodis et telae adiposae perinodalis.

Histopathological diagnosis:

Adenocarcinoma tubulare ventriculi. ~~tubular adenocarcinoma of the stomach.~~

Metastases carcinomatosae in lymphonodis No. III/XIX. Cancer metastases in the lymph nodes No. III/XIX

G2, pT3, pN2

Typus intestinalis sec Lauren.

[REDACTED]

Results of immunohistochemical examination:

HER2 protein stained with HercepTest™ by DAKO.

Score = 2+, verification by the FISH method recommended.

[REDACTED]

[REDACTED]

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file eeec3357-b425-4795-95f0-4f0b58a89ce2 (TCGA-D7-6526.6ED5BBE0-677B-48C3-9733-A08017D6CCA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).